Surgical pathology report (de-identified scan), TCGA case TCGA-ZN-A9VP, project TCGA-MESO (Mesothelioma), tissue source site Brigham and Women's Hospital Division of Thoracic Surgery, specimen TCGA-ZN-A9VP-01A (Primary Tumor).

[page 1 of 4]
Pathology Report

Report Status: Final

Procedure Date:

ICD O-3
Mesothelioma, epithelioid
malignant 9052/3
Site: Pleura NOS C38.4
J 6/13/14

PATHOLOGIC DIAGNOSIS:

A. PORT SITE #1:

Skin and subcutis with acute and chronic inflammation, granulation tissue and foreign body giant cell reaction to polarizable material, negative for tumor.

B. RIB:

Bone and bone marrow with maturing trilineage hematopoiesis, negative for tumor.

C. LEVEL 2R NODE:

One (1) lymph node, negative for tumor.

D. SVC NODE:

One (1) lymph node, negative for tumor.

E. LEVEL 8 NODE:

One (1) lymph node, negative for tumor.

F. LEVEL 4R NODE:

One (1) lymph node, negative for tumor.

G. LEVEL 7 NODE:

One (1) lymph node, negative for tumor.

H. RIGHT LUNG, DIAPHRAGM AND PERICARDIUM, EXTRAPLEURAL PNEUMONECTOMY (INCLUDING FSA):

DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE, SOLID AND TUBULOPAPILLARY PATTERNS.

Tumor involves: chest wall parietal pleura, maximal thickness of 0.8 cm, mediastinal pleura, and diaphragmatic pleura.

Tumor involves visceral pleura.

Visceral pleural involvement by tumor is confluent and includes an interlobar fissure.

Tumor invades lung parenchyma in two foci.

Tumor invades pericardium but does not extend to the inner surface of the pericardium.

Diaphragmatic, pleural and bronchial resection margins are free of tumor.

Tumor is <0.1 cm from apical, lateral, medial, anterior, posterior parietal pleural resection margins.

Lymphovascular invasion is not identified.

Hyaline pleural plaque is not identified.

Mild pulmonary emphysema is present.

"HILAR" LYMPH NODES: Four (4) lymph nodes with no tumor present.

AJCC Classification (7th edition): pT3 N2 (see below, part I).

I. Level 8 node #2.

METASTATIC MESOTHELIOMA, present as a microscopic focus within the subcapsular space of one (1) of three (3) lymph nodes.

[page 2 of 4]
[REDACTED]

Pathology Report

[REDACTED]

[REDACTED]

TISSUE SUBMITTED:

A/1. Port site #1.
B/2. Rib.
C/3. Level 2R node.
D/4. SVC node.
E/5. Level 8 node.
F/6. Level 4R node.
G/7. Level 7 node.
H/8. Right lung, diaphragm and pericardium (FS).
I/9. Level 8 node #2.

O.R. CONSULTATION:

SPECIMEN LABELED "#8 RIGHT LUNG DIAPHRAGM & PERICARDIUM" (FSA):
Bronchial resection margin, negative for tumor.

[REDACTED]

The senior physician certifies that he/she personally conducted a gross and/or microscopic examination of the described specimen(s) and rendered or confirmed the rapid diagnos(es) related thereto.

GROSS DESCRIPTION:

The specimen is received fresh, in eight parts, each labeled with the patient's name and medical record number.

Part A, "#1. Port site #1", consists of a tan/yellow soft tissue fragment (3.9 x 3.9 x 1.4 cm) with attached skin ellipse (2.6 x 0.5 cm). The specimen consists of yellow lobulated adipose tissue with a central area of fibrosis extending from the skin ellipse to the deepest aspect. There are no masses or lesions identified. Representative sections are submitted for histologic examination.

Micro A1-A2: Soft tissue with skin ellipse in A1, 1 frag each, RSS.

Part B, "#2. Rib", consists of a portion of rib (15.2 x 2.1 cm) with attached red/brown fragments of skeletal muscle. There are no masses or lesions identified. A rib bone marrow squeeze is submitted for histologic examination.

Micro B1: Rib bone marrow squeeze, multi frags, RSS.

Part C, "#2. Level 2R node", consists of a tan/pink lymph node (1.2 x 0.6 x 0.5 cm). The specimen is entirely submitted for histologic examination.

Micro C1: Lymph node, 1 frag, ESS.

Part D, "#4. SVC node", consists of a tan/brown/yellow lymph node (1.8 x 0.7 x 0.4 cm). The specimen is entirely submitted for histologic examination.

Micro D1: Lymph node, 1 frag, ESS.

Part E, "#5. Level 8 node", consists of a tan/brown anthracotic lymph node (1.0 x 0.9 x 0.4 cm). The specimen is entirely submitted for histologic examination.

Micro E1: Lymph node, 1 frag, ESS.

Part F, "#6. Level 4R node", consists of a tan/yellow soft tissue fragment (0.6

[page 3 of 4]
Pathology Report

x 0.4 x 0.2 cm). The specimen is entirely submitted for histologic examination.

Micro F1: Soft tissue fragment, 1 frag, ESS.

Part G, "#7. Level 7 node", consists of a tan/brown focally anthracotic lymph node (0.8 x 0.5 x 0.4 cm). The specimen is entirely submitted for histologic examination.

Micro G1: Lymph node, 1 frag, ESS.

Part H, "#8. Right lung, diaphragm and pericardium (FS)", consists of a 1518 gram moderately disrupted extrapleural pneumonectomy specimen (31 x 23 x 7.4 cm) including lung (21 x 14 x 5 cm), parietal pleura, pericardium (7 x 6 cm) and hemidiaphragm (18 x 11 x 1.2 cm). There is a bronchial resection margin (3.3 cm in length x 2.2 cm in diameter) that is submitted en face for frozen section analysis as FSA. The parietal pleura is gray/white/brown, moderately disrupted, and covered with multiple (greater than hundred) partially confluent tan/white nodules (0.5 to 5.0 cm) up to 0.8 cm in thickness. Tumor is present close to all pleural resection margins. The visceral pleura contains multiple (greater than fifty) tan/white partially confluent nodules (up to 1 cm). Tumor bulges (1.7 cm) into lung parenchyma of all lobes and thickened up to (1.2 cm) the entire distance of all intralobar septae. The diaphragmatic parietal pleura is fused (100%) and thickened (1.4 cm) by nodular tumor. The diaphragmatic margins are grossly free of tumor with the closest approach to tumor being 0.5 cm from the anterior margin. The tumor invades to a depth of 0.2 cm into the muscle of diaphragm, but the inferior surface is free of tumor. There are mild emphysematous changes in the peripheral lung parenchyma. There are three firm anthracotic hilar lymph nodes, the largest measuring 1.3 cm in greatest dimension.

Micro H1: Bronchial resection margin, en face, FSA remnant, 1 frag, ESS.
Micro H2: Apical parietal pleural margin, 1 frag, RSS.
Micro H3: Medial parietal pleural margin, 1 frag, RSS.
Micro H4: Lateral parietal pleural margin, 1 frag, RSS.
Micro H5: Anterior parietal pleural margin, 1 frag, RSS.
Micro H6: Posterior parietal pleural margin, 1 frag, RSS.
Micro H7: Medial diaphragm margin, 1 frag, RSS.
Micro H8: Lateral diaphragm margin, 1 frag, RSS.
Micro H9: Anterior diaphragm margin, 1 frag, RSS.
Micro H10: Posterior diaphragm margin, 1 frag, RSS.
Micro H11: Diaphragm, deepest extent of tumor, 1 frag, RSS.
Micro H12: Tumor and intralobar septae, 1 frag, RSS.
Micro H13-H14: Tumor extension into lung parenchyma, 1 frag each, RSS.
Micro H15: Uninvolved upper lobe, 1 frag, RSS.
Micro H16: Uninvolved lower lobe, 1 frag, RSS.
Micro H17: Pericardium with closest extension of tumor to pericardial surface, 1 frag, RSS.
Micro H18: Hilar lymph nodes, 3 frags, ESS.

Part I, "#9. Level 8 node #2", consists of tan/brown/yellow soft tissue fragment (3.0 x 1.1 x 0.6 cm). The specimen is entirely submitted for histologic examination.

Micro I1: Soft tissue fragment, 1 frag, ESS.

By his/her signature below, the senior physician certifies that he/she personally conducted a microscopic examination ("gross only" exam if so stated) of the described specimen(s) and rendered or confirmed the diagnosis(es) related thereto.

[page 4 of 4]
Pathology Report

Source: NCI Genomic Data Commons file e976da59-3096-4ec8-9503-47b7fbe04c25 (TCGA-ZN-A9VP.71F1B1F6-D19F-48F1-BADC-AE97F4DB5958.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).